Surgical pathology report (de-identified scan), TCGA case TCGA-Z2-A8RT, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site IDI-IRCCS, specimen TCGA-Z2-A8RT-06A (Metastatic).

ICD0-5

Melanoma NOS 8720/3
Site @ Forearm C44.6
QW 5/19/14

Name: Omitted

Birth Date:

Address: Omitted

Sex:F

Age:

Lesion site:Left arm 1/3 external distal

Macroscopy:Fragment of adipous tissue of max diameter of 2.5 cm. At the cut there is a nodular formation of max diameter of 1.5 cm

Microscopy:

Diagnosis:Adipose tissue site of localization of scarcely differentiated neoplasia, morphologically compatible with melanoma. BRAF (Real time PCR with test 4800 for mutation V600 Negative

Proposed by

Biopsy by:

Division:

Date of Biopsy

Accepted by :

Pathology Report Date:

Pathology Report

Source: NCI Genomic Data Commons file 1a694284-85c1-46de-bc98-4fe69545a785 (TCGA-Z2-A8RT.890104FC-665B-4FD5-8C2C-601B3453694E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).